Gene-level copy-number profile of tumor specimen TCGA-CM-5348-01A from TCGA case TCGA-CM-5348, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 72.7 years (26,543 days).
Specimen TCGA-CM-5348-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.631b1ce4-f71d-4016-a418-77ac807cea98.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CM-5348-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/39f3b24a-5da3-4427-805f-a85ef2d85448

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 136; copy number 1: 3,241; copy number 2: 37,386; copy number 3: 13,355; copy number 4: 2,968; copy number 5: 673; copy number 6: 5; copy number 7: 1,168; copy number 8: 246; copy number 9: 410; copy number 10: 231.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CM-5348-01A-21D-1717-01): tumor purity 0.57, ploidy 2.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 135 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:184,254,509–190,092,279, 132 genes (broad region; genes not listed).
- chr16:7,004,007–7,304,638, 3 genes: RNU6-328P, AC022206.1, AC007222.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,733 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:95,351,251–95,782,342, 5 genes, copy number 6: LINC01650, AL445218.1, LINC01761, LINC02607, AL683887.1.
- chr6:41,026,895–42,142,620, 50 genes, copy number 5: UNC5CL, OARD1, TSPO2, APOBEC2, NFYA, AL031778.1, ADCY10P1, TREML1, TREM2, TREML2, TREML3P, TREML4, RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2, FOXP4-AS1, LINC01276, FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132.
- chr7:70,972–103,149,560, 1,947 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr8:30,995,802–32,911,598, 18 genes, copy number 8: PURG, WRN, SUMO2P16, AC009563.1, KCTD9P6, AC068672.2, AC068672.3, AC068672.1, AC090816.1, RNA5SP261, NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1, RNU6-663P.
- chr10:125,576,522–126,421,879, 23 genes, copy number 5 (within-gene range 4–5): TEX36, ALDOAP2, AL158835.1, EDRF1-DT, AL158835.3, AL158835.2, EDRF1, EDRF1-AS1, MMP21, UROS, MIR4484, BCCIP, DHX32, Metazoa_SRP, RNU2-42P, FANK1, GNG10P1, FANK1-AS1, ADAM12, RNA5SP328, SAR1AP2, AL589787.2, LINC00601.
- chr10:126,425,930–126,460,957, 1 gene, copy number 5: AL589787.1.
- chr13:18,467,172–30,996,138, 305 genes, copy number 5 (broad region; genes not listed).
- chr15:71,547,280–71,549,832, 1 gene, copy number 5: AC108861.1.
- chr18:43,267,892–49,742,063, 113 genes, copy number 5–7 (broad region; genes not listed).
- chr20:54,153,446–64,313,132, 270 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,210. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
